Somatic mutation profile of tumor specimen TARGET-30-PATDWN-01A (aliquot TARGET-30-PATDWN-01A-01D) from TARGET case TARGET-30-PATDWN, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.9 years (1,435 days).
Specimen TARGET-30-PATDWN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd01fa48-75a8-4b74-8d8d-20b10dafdc4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATDWN-10A (Blood Derived Normal), aliquot TARGET-30-PATDWN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f75bb040-4896-495e-be91-3440ce576755

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR8 | c.1307C>A p.A436E | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.8); PolyPhen benign (0.175); catalogued as COSV51635765; called by muse, mutect2, varscan2
- GNB5 | c.964G>T p.E322* (on ENST00000261837 / NM_016194.4; = p.E280* on NM_006578.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as COSV55898620; called by muse, mutect2, varscan2
- HIRA | c.2171A>C p.N724T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV54273661; called by muse, mutect2, varscan2
- KIFC2 | c.828G>T p.L276F | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV56760507; called by muse, mutect2, varscan2
- MROH2B | c.4733G>T p.C1578F | Missense Mutation (SNP) | VAF 98/196 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV68182624; called by muse, mutect2, varscan2
- OR52K1 | c.263G>T p.W88L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV56903418; called by muse, mutect2, varscan2
- POLN | c.1414G>T p.A472S | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs773283983, COSV67024315; called by muse, mutect2, varscan2
- SLCO5A1 | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52656715; called by muse, mutect2, varscan2
- SPHKAP | c.3579G>C p.E1193D | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60873772; called by muse, mutect2, varscan2
- STAT4 | c.1849A>T p.S617C | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV61828935; called by muse, mutect2, varscan2
- NOS2 | c.2851C>T p.L951= | Silent (SNP) | VAF 2/23 reads (9%) | called by muse, mutect2
